Somatic mutation profile of tumor specimen TCGA-BP-5175-01A (aliquot TCGA-BP-5175-01A-01D-1429-08) from TCGA case TCGA-BP-5175, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 60.1 years (21,949 days).
Specimen TCGA-BP-5175-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f7ca56d-e79b-4afe-9909-81476beb1126.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5175-11A (Solid Tissue Normal), aliquot TCGA-BP-5175-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2acd0d5e-c2dd-4ac4-9fba-c6c42b8de7f6

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 24, Silent 14, Frame Shift Del 5, Nonsense Mutation 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4379T>C p.L1460P | Missense Mutation (SNP) | VAF 60/197 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1057519779, COSV63868845; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VHL | c.221T>A p.V74D | Missense Mutation (SNP) | VAF 7/15 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs5030803, CM961417, COSV56542909, COSV56544662, COSV56545202, COSV56545701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSS1 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV60221456; called by muse, mutect2, varscan2
- BRD1 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV53458607; called by muse, mutect2, varscan2
- C2orf49 | c.443G>A p.S148N | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV51528108; called by muse, mutect2, varscan2
- COL24A1 | c.2311-1G>T p.X771_splice | Splice Site (SNP) | VAF 31/162 reads (19%) | catalogued as COSV65306653; called by muse, mutect2, varscan2
- DEDD | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV63502065; called by muse, mutect2
- FBXO40 | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57524920; called by muse, mutect2, varscan2
- GPATCH4 | c.512C>A p.T171K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV58040439; called by muse, mutect2, varscan2
- GPR78 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs202089891, COSV66763299; called by muse, mutect2
- MAPK8IP1 | c.1541C>A p.P514H | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53798233; called by muse, mutect2, varscan2
- MS4A10 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 103/291 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57632934; called by muse, mutect2, varscan2
- MUC2 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs745895148; called by muse, mutect2, varscan2
- NDST4 | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV52124066; called by muse, mutect2, varscan2
- OR5AU1 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1566572740, COSV58615737; called by muse, mutect2, varscan2
- PCNX3 | c.5086C>T p.P1696S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV63137763; called by muse, mutect2, varscan2
- PDE6A | c.2530G>T p.G844* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as COSV54928441; called by muse, mutect2, varscan2
- PTGER2 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.095); catalogued as COSV55419225; called by muse, mutect2, varscan2
- SSRP1 | c.820A>C p.I274L | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV53480080; called by muse, mutect2, varscan2
- SYT15 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV65432314; called by muse, mutect2, varscan2
- TMEM171 | c.135G>C p.Q45H | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55130735; called by muse, mutect2
- TNXB | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64481056; called by muse, mutect2, varscan2
- UBA6 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59178294; called by muse, mutect2, varscan2
- UBR4 | c.8947C>T p.Q2983* | Nonsense Mutation (SNP) | VAF 51/185 reads (28%) | catalogued as COSV64392095; called by muse, mutect2, varscan2
- WT1 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.029); catalogued as COSV60074312; called by muse, mutect2, varscan2
- ZNF347 | c.15G>C p.Q5H | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV61969264; called by muse, mutect2, varscan2
- ZNF705A | c.12+1G>T p.X4_splice | Splice Site (SNP) | VAF 16/365 reads (4%) | catalogued as COSV63733284; called by muse, mutect2
- ANKRD6 | c.1491del p.L498Wfs*5 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- CUL3 | c.1152_1153del p.P385* | Frame Shift Del (DEL) | VAF 29/125 reads (23%) | called by pindel, varscan2
- DST | c.17413_17425del p.V5805Mfs*36 (on ENST00000361203 / NM_001374722.1; = p.V3502Mfs*36 on NM_015548.5) | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- PCP4L1 | c.193del p.D65Ifs*35 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- SLC22A8 | c.220del p.L74Sfs*36 | Frame Shift Del (DEL) | VAF 66/394 reads (17%) | called by mutect2, pindel, varscan2
- SYNRG | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD9 | c.1737C>A p.T579= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as COSV60247323; called by muse, mutect2, varscan2
- CDH12 | c.1359G>A p.A453= | Silent (SNP) | VAF 106/401 reads (26%) | catalogued as rs371565243, COSV66424245; called by muse, mutect2, varscan2
- CLEC16A | c.2400C>G p.R800= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV55490246; called by muse, mutect2, varscan2
- EDN3 | c.333C>T p.C111= | Silent (SNP) | VAF 70/271 reads (26%) | catalogued as COSV61108474; called by muse, mutect2, varscan2
- KIDINS220 | c.324T>G p.L108= | Silent (SNP) | VAF 55/219 reads (25%) | catalogued as COSV56754836; called by muse, mutect2, varscan2
- KNDC1 | c.2520G>A p.P840= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs756038042, COSV58839918; called by muse, mutect2
- MRPS18A | c.399T>A p.P133= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV64522029; called by muse, mutect2, varscan2
- MYH7 | c.2589A>G p.L863= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as COSV62520526, COSV62524789; called by muse, mutect2
- MYH7B | c.1566C>A p.I522= | Silent (SNP) | VAF 58/183 reads (32%) | catalogued as COSV53416555, COSV53421379; called by muse, mutect2, varscan2
- NKD1 | c.114C>T p.I38= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV51691952; called by muse, mutect2, varscan2
- OR6C3 | c.120G>T p.L40= | Silent (SNP) | VAF 39/385 reads (10%) | catalogued as COSV65571317; called by muse, mutect2, varscan2
- PDZD2 | c.7017C>T p.I2339= | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as rs1259701237, COSV56861704, COSV56867862; called by muse, mutect2
- PLXNB2 | c.1887C>A p.S629= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV63782510; called by muse, mutect2, varscan2
- RUNX1T1 | c.1500C>T p.D500= (on ENST00000265814 / NM_001198628.1; = p.D473= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs767484299, COSV56151051; called by muse, mutect2, varscan2
